Somatic mutation profile of tumor specimen MMRF_1753_1_BM_CD138pos (aliquot MMRF_1753_1_BM_CD138pos_T2_KBS5U_L05364) from MMRF case MMRF_1753, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.7 years (23,629 days).
Specimen MMRF_1753_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c9ede58-df55-4345-8fb2-94ed2a490b54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1753_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1753_1_PB_Whole_C3_KBS5U_L05359; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81a45398-9b22-4c61-8ff9-cf614fae9d7f

The open-access MAF lists 60 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 14, Intron 9, 5'UTR 4, Silent 4, Splice Site 1, RNA 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGAP3 | c.112A>T p.I38L | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs542653008; called by muse, mutect2, varscan2
- CILP2 | c.3289G>A p.G1097S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765654456; called by muse, mutect2, varscan2
- DMRT3 | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV51904804; called by muse, mutect2
- IGHJ5 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 37/68 reads (54%) | PolyPhen benign (0.086); catalogued as rs781822844; called by muse, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV2-70 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs374979633; called by muse, varscan2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IGKV1D-43 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs554861603; called by muse, varscan2
- IGLV6-57 | c.219A>C p.Q73H | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as rs553972656; called by muse, varscan2
- PDCD11 | c.4816G>A p.D1606N | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV99037857; called by muse, mutect2, varscan2
- RAB13 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456890575, COSV55132720; called by muse, mutect2, varscan2
- TTC6 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs747956919; called by muse, mutect2, varscan2
- ZNF274 | c.1718A>G p.N573S (on ENST00000610905; = p.N468S on NM_016324.3) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs375978076; called by muse, mutect2, varscan2
- ARMCX4 | c.572T>G p.V191G (on ENST00000433011; = p.V87G on NM_001256155.2) | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CHD6 | c.7748T>G p.L2583* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- FSIP2 | c.20180T>A p.I6727N | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- IGHV1-69D | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- IQGAP2 | c.1613-2A>T p.X538_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PLCB4 | c.2002A>G p.N668D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PPFIA2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SETDB2 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SNX27 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUCO | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXLNB | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DCC | c.1104A>G p.G368= | Silent (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- GLRA3 | c.525C>T p.L175= | Silent (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- IGHJ4 | c.24A>G p.G8= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as rs374255016; called by muse, varscan2
- SPOCK3 | c.696A>T p.T232= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- AURKC | c.-97G>A | 5'UTR (SNP) | VAF 20/138 reads (14%) | catalogued as rs1198612702; called by muse, mutect2, varscan2
- C11orf24 | c.*17G>A | 3'UTR (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- CCND2 | c.*3114A>G | 3'UTR (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- DOC2A | c.342+38G>T | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2
- EIF2D | c.*18C>T | 3'UTR (SNP) | VAF 12/410 reads (3%) | catalogued as rs1315826269, COSV99662763; called by muse, mutect2
- ELAPOR1 | c.*116C>A | 3'UTR (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- GK5 | c.816+183G>A | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV101242101; called by muse, mutect2
- GLIS3 | c.*114G>C | 3'UTR (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- LTB | c.162+44G>A | Intron (SNP) | VAF 44/98 reads (45%) | catalogued as rs369223933; called by muse, mutect2, varscan2
- MAN1A1 | c.-174G>A | 5'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs1264520851; called by muse, mutect2
- MMP16 | c.*7156T>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- MMS22L | c.607-114G>A | Intron (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2067T>A | RNA (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- NUDT16 | c.408+287C>T | Intron (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- PAX7 | c.-511T>C | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- POU2F2 | chr19:42089677 T>A | 3'Flank (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- PURA | c.*1155T>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- RSF1 | c.*10dup | 3'UTR (INS) | VAF 64/166 reads (39%) | catalogued as rs754227315; called by mutect2, varscan2
- S1PR3 | c.-147-3397C>A | Intron (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- SIL1 | c.-10-97C>T | Intron (SNP) | VAF 59/297 reads (20%) | called by muse, mutect2, varscan2
- SLC30A1 | c.*3442_*3443del | 3'UTR (DEL) | VAF 4/41 reads (10%) | catalogued as rs1188428814; called by mutect2, pindel, varscan2
- ST3GAL1 | c.*4291_*4298del | 3'UTR (DEL) | VAF 44/102 reads (43%) | called by mutect2, pindel, varscan2
- SULT1C4 | c.-267A>C | 5'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- SYNPO2L | c.*72C>A | 3'UTR (SNP) | VAF 9/175 reads (5%) | catalogued as COSV100831826; called by muse, mutect2
- TMEM170B | c.*4125G>T | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- TRIM64B | c.*622A>G | 3'UTR (SNP) | VAF 110/560 reads (20%) | catalogued as rs1337544402; called by muse, mutect2, varscan2
- TXNDC5 | c.*574T>G | 3'UTR (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- VPS13C | c.10863+754C>G | Intron (SNP) | VAF 72/159 reads (45%) | called by muse, mutect2, varscan2
- ZNF462 | c.6832+543C>A | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
